Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A7GJ, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A7GJ-01A (Primary Tumor).

[page 1 of 4]
Diagnosis:

A: Uterus, hysterectomy.

Cervix, total removal.

- Squamous metaplasia.

Endometrium, total removal.

- Weakly proliferative endometrium.

Myometrium, total removal.

- Leiomyomata, mural and subserosal (8 cm in greatest diameter).

Right ovary, total removal.

- Corpus luteum.

Right fallopian tube, total removal.

- No specific pathologic abnormality.

Left ovary, total removal.

- Follicular cyst.

Left fallopian tube, total removal.

- No specific pathologic abnormality.

B: Kidney, right, nephrectomy.

- Renal cell carcinoma, chromophobe cell type, mixed classic and eosinophilic variant; positive capsular invasion, negative perirenal fat extension; positive lymphovascular space invasion, negative renal artery margin, negative renal vein margin, negative ureter margin.

Adrenal gland, right, total removal.

- Adrenal gland present, negative for malignancy.

Comment:

See report. Drs. and have reviewed specimen B and concur with the diagnosis.

Clinical History:

Year-old female with a pelvic mass. Per the , the patient has right renal and uterine masses. The uterine mass appears to be consistent with "fibroid" on imaging. The renal mass appears similar.

ICD-O-3
Carcinoma, renal cell
Chromophobe type 8317/3
Site (R) Kidney NOS
C64.9
JW 9/24/13

[page 2 of 4]
Gross Description:

Received are two appropriately labeled containers.

Container A:

Adnexa: present

Weight: 850 grams

Shape: significantly distorted by the presence of multiple leiomyomata

Dimensions:

height: 14.0 cm

anterior to posterior width: 13.0 cm

breadth at fundus: 13.0 cm

Serosa: smooth, tan

Cervix:

length of endocervical canal: 4.0 cm

ectocervix: width = 2.8 cm; appears white/tan and smooth

endocervix: width = 0.3 cm; appears tan and smooth with few Nabothian cysts

noted measuring approximately 0.1 cm each

Endometrium:

length of endometrial cavity: difficult to assess due to distortion, approximately 6.0 cm

width of endometrial cavity at fundus: difficult to assess, approximately 2.0 cm

thickness of endometrial lining: 0.2 cm

other findings: The endometrial surface is smooth and tan/brown

Myometrium:

thickness of wall: approximately 1.5 cm in area uninvolved by leiomyoma

other findings: there are multiple intramural and subserosal leiomyomata

present; these range in size from 0.4 cm up to approximately 8.0 cm in greatest dimension

Adnexa:

right ovary: 2.8 x 2.4 x 1.2 cm

cut surface: tan/white and smooth

external surfaces: tan and cerebriform; a brown, cystic structure is present measuring 2.0 x 1.0 x 0.4 cm, adjacent to the ovary. It is grossly consistent with hemorrhagic cyst.

right fallopian tube: 10.0 cm in length, 0.7 cm in diameter

other findings: grossly unremarkable

left ovary: 3.0 x 2.0 x 1.0 cm

external surface: tan/white and cerebriform

cut surfaces: tan/white/brown and mottled

left fallopian tube: 10.0 x 0.8 cm

other findings: no grossly identifiable abnormalities

Other comments: The myometrium ranges from 1.8 cm up to 8.5 cm in greatest

dimension. The myometrium is tan and trabeculated and distorted by multiple leiomyomata. The cut surface of the leiomyomata are smooth, white/tan, homogeneous and whorled with a bulging appearance.

[page 3 of 4]
Block Summary:

A1 - anterior cervix

A2 - posterior cervix

A3,A4 - anterior corpus

A5,A6 - posterior corpus

A7 - right ovary and tube

A8 - left ovary and tube

A9 - three subserosal leiomyomata, representative sections

A10 - largest leiomyomata, representative section

A11 - additional leiomyomata sections

Container B:

Specimen fixation: formalin

Type of specimen: nephrectomy

Size and weight of specimen: 1,550 grams; 21.0 x 15.0 x 11.0 cm, the residual kidney measures 13.0 x 7.0 x 3.5 cm, the adrenal gland measures 9.0 x 1.5 x 0.5 cm

Presence/absence of adrenal gland: present, no abnormalities noted

Tumor description: superior and posterior portion of kidney - The cut surface is yellow/white and soft, consistent with necrosis.

Tumor size: 15.0 x 11.0 x 9.0 cm

Presence/absence of multicentricity: absent

Confinement/Non-confinement to kidney: difficult to assess, the tumor mass extends up to and compresses the adrenal gland; it appears to be well circumscribed

Extent of invasion:

Perirenal adipose tissue: does not grossly involve

Renal vein: does not grossly involve

Ureter: does not grossly involve

Other organs: compresses but does not appear to involve the adrenal gland

Surgical margins:

Perirenal adipose tissue: grossly negative

Renal vein: grossly negative

Renal artery: grossly negative

Ureter: grossly negative

[page 4 of 4]
Description of kidney away from tumor: congested and brown/red

Lymph nodes (hilar): not identified

Tissue submitted for special investigations: not applicable

Comment: The area at the adrenal gland is inked yellow. The remainder of the specimen is inked blue. Representative sections are submitted as per the block summary.

Block Summary:

B1 - ureter and vessel margin

B2 - representative section, normal appearing kidney

B3 - tumor at adrenal gland

B4,B5 - tumor with adjacent normal

B6,B7 - tumor at blue inked margin

Light Microscopy:

Light microscopic examination is performed by Dr.

Histologic tumor type/subtype: renal cell carcinoma

Histologic grade (if applicable): Furhman grade 3 (of 3)

Tumor size (greatest dimension): 15.0 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: capsular invasion

Renal vein: negative

Ureter: negative

Renal artery: negative

Lymphovascular: positive

Adrenal gland for metastatic renal cell carcinoma: negative

Source: NCI Genomic Data Commons file 8e7343cc-f199-457a-979d-0023a3162a38 (TCGA-UW-A7GJ.62D556D5-4925-44BB-BE47-8DF557F94609.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).